Somatic mutation profile of tumor specimen HCM-BROD-0557-C43-06A (aliquot HCM-BROD-0557-C43-06A-11D-A80U-36) from HCMI case HCM-BROD-0557-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 31.6 years (11,559 days).
Specimen HCM-BROD-0557-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8007d08d-d82b-4915-99bc-9e8d8df3e153.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0557-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0557-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7fdbf0e-a60b-4aef-876b-f6b91b12a143

The open-access MAF lists 526 somatic variants for this specimen: 334 protein-altering or splice-affecting, 169 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 306, Silent 169, Intron 13, Nonsense Mutation 13, Frame Shift Del 6, 5'Flank 5, 3'UTR 3, Splice Region 3, Splice Site 3, Frame Shift Ins 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 128/315 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- A4GNT | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs892441560; called by muse, mutect2, varscan2
- ACKR3 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 145/358 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56020440, COSV56021095; called by muse, mutect2, varscan2
- ADGRE1 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as COSV99165303; called by muse, mutect2, varscan2
- AGBL4 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 167/412 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1205278617; called by muse, mutect2, varscan2
- ALB | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV55742933; called by muse, mutect2, varscan2
- ALS2CL | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59673039; called by muse, mutect2
- AMY2A | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 131/303 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70214313, COSV70214392; called by muse, mutect2, varscan2
- AMY2A | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs1233637366, COSV101340608; called by muse, mutect2, varscan2
- APCS | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs746370899, COSV54818560; called by muse, mutect2, varscan2
- ARHGEF17 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 551/758 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs764091725; called by muse, mutect2, varscan2
- ATP6V0A2 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 100/245 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV57747578; called by muse, mutect2, varscan2
- BEST2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 147/368 reads (40%) | catalogued as rs776776362; called by muse, mutect2, varscan2
- C11orf58 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 266/367 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV57178116; called by muse, mutect2, varscan2
- C11orf58 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 265/365 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99930391; called by muse, mutect2, varscan2
- CACNA2D3 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 125/300 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55535361; called by muse, mutect2, varscan2
- CANT1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 168/409 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.244); catalogued as rs748328987; called by muse, mutect2, varscan2
- CCDC181 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs530288123, COSV63155897; called by muse, mutect2, varscan2
- CD109 | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 116/357 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as COSV54645579; called by muse, mutect2
- CD55 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs924315999, COSV58576904; called by muse, mutect2, varscan2
- CD55 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201591726, COSV58577432; called by muse, mutect2, varscan2
- CDK12 | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 104/276 reads (38%) | catalogued as COSV71002558; called by muse, mutect2, varscan2
- CEACAM16 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 164/434 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1424899201; called by muse, mutect2, varscan2
- CFAP44 | c.4909G>A p.D1637N | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs557730278, COSV57661548; called by muse, mutect2, varscan2
- CHL1 | c.3136C>T p.R1046C (on ENST00000397491 / NM_001253387.1; = p.R1062C on NM_006614.4) | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs555557287, COSV56600202; called by muse, mutect2, varscan2
- CILP | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 95/254 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV56021717; called by muse, mutect2, varscan2
- CLASP2 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 141/399 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.909); catalogued as rs1369924707, COSV100224038; called by muse, mutect2, varscan2
- CNTNAP2 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100663519; called by muse, mutect2, varscan2
- COL1A2 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 154/359 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs72659343, CM041284, COSV51955047; called by muse, mutect2, varscan2
- COL5A1 | c.3175C>T p.P1059S | Missense Mutation (SNP) | VAF 307/348 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV65669642; called by muse, mutect2, varscan2
- CRB1 | c.4130G>A p.G1377E | Missense Mutation (SNP) | VAF 139/332 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052327653, COSV66349180; called by muse, mutect2, varscan2
- CSMD1 | c.10409C>T p.P3470L (on ENST00000520002; = p.P3469L on NM_033225.6) | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs767156556; called by muse, mutect2, varscan2
- CSMD1 | c.2653C>T p.R885C (on ENST00000520002; = p.R884C on NM_033225.6) | Missense Mutation (SNP) | VAF 159/295 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310702695, COSV59352917, COSV99064856; called by muse, mutect2, varscan2
- CSMD3 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.931); catalogued as COSV52167315, COSV52262612; called by muse, mutect2, varscan2
- CTNNA3 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 124/169 reads (73%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); catalogued as rs1392043478; called by muse, mutect2, varscan2
- CYLC2 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 200/241 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV66339524; called by muse, mutect2, varscan2
- CYP2D6 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 215/602 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs747089665; called by muse, mutect2, varscan2
- DEFB119 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 96/246 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs267605872, COSV59266560; called by muse, mutect2, varscan2
- DLX5 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 150/376 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99756472; called by muse, mutect2, varscan2
- DNAH1 | c.10602G>A p.M3534I | Missense Mutation (SNP) | VAF 143/309 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs763222753; called by muse, mutect2, varscan2
- DNAH5 | c.11031G>A p.V3677= | Splice Region (SNP) | VAF 78/204 reads (38%) | catalogued as rs1300306339, COSV99453372; called by muse, mutect2, varscan2
- DNAH6 | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs772882396, COSV52860572; called by muse, mutect2, varscan2
- DNAJC8 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 158/391 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1370615414; called by muse, mutect2, varscan2
- DSCAM | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 332/557 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68024399; called by muse, mutect2, varscan2
- EPHA3 | c.2853G>A p.M951I | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.037); catalogued as COSV60729791; called by muse, mutect2, varscan2
- ERCC2 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 246/556 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.15); catalogued as rs1363432651, COSV55541226; called by muse, mutect2, varscan2
- ERICH1 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 110/474 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.031); catalogued as rs1285611999; called by muse, mutect2, varscan2
- EYA1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs780203392, COSV58160409; called by muse, mutect2, varscan2
- FBN1 | c.8189G>A p.R2730Q | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs200231626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs376398925, COSV52514403; called by muse, mutect2, varscan2
- FBXW8 | c.1162G>A p.G388S (on ENST00000309909; = p.G426S on NM_012174.1) | Missense Mutation (SNP) | VAF 150/327 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV99997461; called by muse, mutect2, varscan2
- FER1L5 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 82/214 reads (38%) | catalogued as rs866147948, COSV70069045; called by muse, mutect2, varscan2
- FNDC3A | c.2179C>T p.P727S (on ENST00000492622 / NM_001079673.2; = p.P671S on NM_014923.5) | Missense Mutation (SNP) | VAF 141/313 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs747587950; called by muse, mutect2, varscan2
- GCSAML | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867795960, COSV63577305; called by muse, mutect2, varscan2
- GLI2 | c.2393C>T p.S798L (on ENST00000361492 / NM_001374353.1; = p.S815L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 274/684 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1026630572; called by muse, mutect2, varscan2
- GPHN | c.1690C>T p.R564C (on ENST00000315266 / NM_001377519.1; = p.R597C on NM_020806.5) | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs1360125120, COSV104400759; called by muse, mutect2, varscan2
- GPI | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 107/290 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as rs767547881; called by muse, mutect2, varscan2
- GPI | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as rs1320084711, COSV62893917; called by muse, mutect2, varscan2
- GPR176 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV100137071; called by muse, mutect2, varscan2
- GRIA4 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 193/300 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56891574; called by muse, mutect2, varscan2
- H1-7 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 193/527 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as rs1373989811; called by muse, mutect2, varscan2
- HDAC9 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 213/464 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs527740786, COSV67781752; called by muse, mutect2, varscan2
- HIP1R | c.3073C>T p.R1025W | Missense Mutation (SNP) | VAF 154/370 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs149673932; called by muse, varscan2
- HNRNPUL2 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 71/443 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs1387817513; called by muse, mutect2, varscan2
- HS3ST1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 114/290 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs368275390; called by mutect2, varscan2
- IGSF9 | c.1909C>T p.R637W (on ENST00000368094 / NM_001135050.2; = p.R621W on NM_020789.4) | Missense Mutation (SNP) | VAF 178/483 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1480973609, COSV100829611; called by muse, mutect2, varscan2
- IMPG1 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 119/270 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV100886337, COSV64055776; called by muse, mutect2, varscan2
- INPP5B | c.2174G>A p.R725K (on ENST00000373023; = p.R645K on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100886603; called by muse, mutect2, varscan2
- INPPL1 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 211/317 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53359298; called by muse, mutect2, varscan2
- ITGB2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 251/562 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1038898860, COSV56614762; called by muse, mutect2, varscan2
- IYD | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 130/176 reads (74%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); catalogued as rs777194249, COSV57604315; called by muse, mutect2, varscan2
- JAKMIP1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV51522350; called by muse, mutect2, varscan2
- KCNH6 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs200388894, COSV59005511; called by muse, mutect2, varscan2
- KDM4B | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 187/437 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV50208384; called by muse, mutect2, varscan2
- KIF1B | c.4714G>A p.E1572K (on ENST00000377086 / NM_001365952.1; = p.E1526K on NM_015074.3) | Missense Mutation (SNP) | VAF 110/225 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as rs1472927510; called by muse, mutect2, varscan2
- KIF2B | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 187/443 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.231); catalogued as COSV99275798; called by muse, mutect2, varscan2
- KIRREL1 | c.917T>C p.F306S | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV63291737; called by muse, mutect2, varscan2
- KLRF1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.92); catalogued as COSV99684382; called by muse, mutect2, varscan2
- KRBA1 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 218/529 reads (41%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as rs1457120871; called by muse, mutect2
- KRT85 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs756221275, COSV57737514, COSV99225480; called by muse, mutect2, varscan2
- KRTAP27-1 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 143/529 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as rs753785111; called by muse, mutect2, varscan2
- LDAH | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 104/299 reads (35%) | catalogued as rs1337123037, COSV52970284; called by muse, mutect2, varscan2
- LRGUK | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs953665896; called by muse, mutect2, varscan2
- LRP1B | c.8314C>T p.R2772C | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as rs1247290776; called by muse, mutect2, varscan2
- MAGEC1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 216/255 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as rs374380387; called by muse, mutect2, varscan2
- MAP7D3 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 140/187 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773689546, COSV60170155; called by muse, mutect2, varscan2
- MED12L | c.6136C>T p.Q2046* | Nonsense Mutation (SNP) | VAF 151/415 reads (36%) | catalogued as COSV56386065; called by muse, mutect2, varscan2
- MGAM2 | c.4597C>T p.P1533S | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101522957; called by muse, mutect2, varscan2
- MGAT1 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 116/352 reads (33%) | PolyPhen benign (0.052); catalogued as rs1230770357, COSV57134298; called by muse, mutect2, varscan2
- MIB2 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 115/626 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV61542620; called by muse, mutect2, varscan2
- MPP7 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as rs767641039, COSV61731060; called by muse, mutect2, varscan2
- MUC16 | c.35800T>A p.F11934I | Missense Mutation (SNP) | VAF 135/307 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV67463794; called by muse, mutect2, varscan2
- MUC16 | c.25315G>A p.E8439K | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.047); catalogued as rs758147569; called by muse, mutect2, varscan2
- MXRA5 | c.7639C>T p.P2547S | Missense Mutation (SNP) | VAF 87/98 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV54228015; called by muse, mutect2, varscan2
- MYCN | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 123/279 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV55257630; called by muse, mutect2, varscan2
- MYOCD | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 137/340 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs767925734, COSV58498174, COSV58501218; called by muse, mutect2, varscan2
- NDRG4 | c.92C>T p.P31L (on ENST00000570248 / NM_001378344.1; = p.P63L on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 258/346 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773985953; called by muse, mutect2, varscan2
- NELL1 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1282602015, COSV54266218; called by muse, mutect2, varscan2
- NLRP11 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 143/326 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1419096001; called by muse, mutect2, varscan2
- NOS1 | c.2962+1G>A p.X988_splice | Splice Site (SNP) | VAF 90/192 reads (47%) | catalogued as COSV57616870; called by muse, mutect2, varscan2
- NOTCH2 | c.5123C>T p.S1708F | Missense Mutation (SNP) | VAF 131/276 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs761415665, COSV56687314, COSV56702208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUGGC | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs200299828; called by muse, mutect2, varscan2
- OCM2 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 140/317 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs761610491, COSV99990764; called by muse, mutect2, varscan2
- OR10J3 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs748268654, COSV100171598, COSV59955282; called by muse, mutect2, varscan2
- OR2W3 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 133/345 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64456004, COSV64456927; called by muse, mutect2, varscan2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 268/404 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR5D14 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 78/417 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV59456072; called by muse, mutect2, varscan2
- OR8B2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 206/378 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1443464287; called by muse, mutect2
- OTX2 | c.506C>T p.S169F (on ENST00000408990 / NM_172337.3; = p.S177F on NM_021728.4) | Missense Mutation (SNP) | VAF 357/597 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59766304; called by muse, mutect2, varscan2
- PAPLN | c.1790G>C p.G597A (on ENST00000554301; = p.G570A on NM_173462.4) | Missense Mutation (SNP) | VAF 432/796 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as COSV53716638; called by mutect2, varscan2
- PCDH11X | c.1703C>A p.P568Q | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53471285; called by muse, mutect2, varscan2
- PCDH11Y | c.263C>T p.S88F (on ENST00000400457 / NM_032973.2; = p.S77F on NM_032971.3) | Missense Mutation (SNP) | VAF 192/228 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53087313; called by muse, mutect2, varscan2
- PCDH18 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs1430122137, COSV61267510; called by muse, mutect2, varscan2
- PCDHGA7 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 97/246 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); catalogued as COSV53946956; called by muse, mutect2, varscan2
- PCLO | c.5621C>T p.P1874L | Missense Mutation (SNP) | VAF 107/274 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs371631647, COSV61631945; called by muse, mutect2, varscan2
- PGBD1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV52556944; called by muse, mutect2, varscan2
- PLS3 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56776518; called by muse, mutect2, varscan2
- PLVAP | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 224/513 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.423); catalogued as rs561048879, COSV53083952, COSV53088077; called by muse, mutect2, varscan2
- POM121L2 | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 137/356 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV66277542; called by muse, mutect2, varscan2
- PPP6R1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 128/294 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as rs1157181885; called by muse, mutect2, varscan2
- PRKAA2 | c.786A>G p.I262M | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771303312; called by muse, mutect2, varscan2
- PSMD6 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 166/468 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs1391025180; called by mutect2, varscan2
- PTPRD | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 155/183 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV61936192, COSV61975980; called by muse, mutect2, varscan2
- PTPRT | c.4042C>T p.P1348S | Missense Mutation (SNP) | VAF 153/407 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.065); catalogued as rs539998222, COSV61971201; called by muse, mutect2, varscan2
- RAB43 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs748757556; called by muse, mutect2, varscan2
- RANBP2 | c.3275C>T p.T1092I | Missense Mutation (SNP) | VAF 112/267 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1435623130; called by muse, mutect2, varscan2
- REV3L | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 71/104 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs746372132, COSV62615391; called by muse, mutect2, varscan2
- RGPD3 | c.2983G>A p.G995R | Missense Mutation (SNP) | VAF 148/450 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58738872; called by muse, mutect2, varscan2
- RNF113B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 189/472 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs199939990, COSV57434212; called by muse, mutect2, varscan2
- RNF213 | c.6070C>T p.R2024* | Nonsense Mutation (SNP) | VAF 155/338 reads (46%) | catalogued as COSV60396335; called by muse, mutect2, varscan2
- RPGRIP1 | c.2942G>A p.R981Q | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376213645; called by muse, mutect2, varscan2
- RPS6KB2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 274/404 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1314670038; called by muse, mutect2, varscan2
- RPS6KB2 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748416853; called by muse, mutect2, varscan2
- RYR3 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370528698; called by muse, mutect2, varscan2
- SEPTIN9 | c.149C>T p.P50L (on ENST00000427177 / NM_001113491.2; = p.P32L on NM_006640.4) | Missense Mutation (SNP) | VAF 169/381 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV61210110; called by muse, mutect2, varscan2
- SEZ6L | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50699220; called by muse, mutect2, varscan2
- SIK3 | c.2768C>T p.S923F (on ENST00000445177 / NM_001366686.2; = p.S881F on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV52611461; called by muse, mutect2, varscan2
- SKAP2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344115486; called by muse, mutect2, varscan2
- SLC22A12 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 73/421 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs759297223, COSV60572779; called by muse, mutect2, varscan2
- SLC35F3 | c.125C>T p.P42L (on ENST00000366617 / NM_001300845.1; = p.P111L on NM_173508.4) | Missense Mutation (SNP) | VAF 170/475 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1343882726, COSV64020069; called by muse, mutect2, varscan2
- SLC5A5 | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99033085; called by muse, mutect2, varscan2
- SLC9A5 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 190/272 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1316587688; called by muse, mutect2, varscan2
- SMO | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 268/649 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1189276452; called by muse, varscan2
- SPATA13 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 123/372 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.03); catalogued as rs528255708, COSV57975958; called by muse, mutect2, varscan2
- TANC2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV67343879; called by muse, mutect2, varscan2
- TCAP | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 109/280 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV54092384; called by muse, mutect2, varscan2
- TET3 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69645315; called by muse, mutect2, varscan2
- TGIF2LX | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 120/143 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs1244960748; called by muse, mutect2, varscan2
- TGM7 | c.1680G>A p.E560= | Splice Region (SNP) | VAF 79/186 reads (42%) | catalogued as COSV71772907; called by muse, mutect2, varscan2
- TIMELESS | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 62/181 reads (34%) | catalogued as rs267603584, COSV57508974, COSV57515293; called by muse, mutect2, varscan2
- TMEM132E | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 189/505 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776520313; called by muse, mutect2, varscan2
- TMEM185B | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 175/444 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.079); catalogued as rs899097862; called by muse, mutect2, varscan2
- TMPRSS9 | c.581C>T p.S194F (on ENST00000648592; = p.S160F on NM_182973.2) | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs770258343, COSV60227090; called by muse, mutect2, varscan2
- TNFRSF17 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 115/309 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50000400; called by muse, mutect2, varscan2
- TRIM25 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 167/366 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs533748559; called by muse, mutect2, varscan2
- UBR2 | c.4118C>T p.A1373V | Missense Mutation (SNP) | VAF 116/252 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV65752050; called by muse, mutect2, varscan2
- UGT2A1 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 134/278 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036004763; called by muse, mutect2, varscan2
- UNC13A | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 192/540 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as rs756578402; called by muse, varscan2
- UNC79 | c.6643-1G>A p.X2215_splice (on ENST00000393151 / NM_001346218.2; = p.X2038_splice on NM_020818.5) | Splice Site (SNP) | VAF 81/279 reads (29%) | catalogued as COSV56371891, COSV56399831; called by muse, mutect2, varscan2
- UPK1B | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 113/278 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs769296250, COSV51766303; called by muse, mutect2, varscan2
- VPS72 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 150/377 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs753843573, COSV99765980; called by muse, mutect2, varscan2
- VWA5B1 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 179/372 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as rs1438103590; called by muse, mutect2, varscan2
- WFDC5 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 131/355 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as rs1366889691; called by muse, mutect2, varscan2
- WNT2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 139/365 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV55413034; called by muse, mutect2, varscan2
- XIRP2 | c.389G>A p.R130K (on ENST00000628543; = p.R305K on NM_152381.6) | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99747444; called by muse, mutect2, varscan2
- ZC3H6 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 121/346 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV59670659; called by muse, mutect2, varscan2
- ZC3H7B | c.2866G>C p.D956H | Missense Mutation (SNP) | VAF 108/480 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); catalogued as COSV60961738; called by muse, mutect2, varscan2
- ZFHX4 | c.7298C>T p.S2433L | Missense Mutation (SNP) | VAF 222/475 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1290135493, COSV99257705; called by muse, mutect2, varscan2
- ZNF217 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 191/473 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs771475503; called by muse, mutect2, varscan2
- ZNF268 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.42); catalogued as COSV57214426; called by muse, mutect2, varscan2
- ZNF618 | c.709G>A p.E237K (on ENST00000374126 / NM_001318042.2; = p.E205K on NM_133374.2) | Missense Mutation (SNP) | VAF 260/312 reads (83%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.318); catalogued as rs1335639588; called by muse, mutect2, varscan2
- ZNF626 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV74129566, COSV74130913; called by muse, mutect2, varscan2
- ZSCAN4 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 77/174 reads (44%) | catalogued as rs267605731; called by muse, mutect2, varscan2
- ABCA12 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ACO2 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACRV1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 73/526 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ACSM2A | c.573G>A p.W191* (on ENST00000219054; = p.W112* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 56/160 reads (35%) | called by muse, mutect2, varscan2
- ADAM28 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL3 | c.2503G>A p.G835S | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGER | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 266/630 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- AHSG | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 220/417 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP8L | c.1087_1089delinsTG p.R363* | Frame Shift Del (DEL) | VAF 142/455 reads (31%) | called by pindel, varscan2*
- AKNAD1 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- AL441992.2 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 244/299 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- ANAPC7 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANK3 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 88/115 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP8A1 | c.2944A>T p.N982Y | Missense Mutation (SNP) | VAF 140/376 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AVL9 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ2B | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BICRA | c.4045C>T p.P1349S | Missense Mutation (SNP) | VAF 182/524 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BPIFC | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 138/345 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BTBD8 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 108/264 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- C1orf116 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 131/336 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- C1orf74 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 147/373 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C4A | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 142/506 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- CABLES2 | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CABP2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 325/497 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CADM3 | c.517C>T p.H173Y (on ENST00000368125 / NM_001127173.3; = p.H207Y on NM_021189.5) | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CALCB | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 391/522 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- CALCRL | c.115A>T p.N39Y | Missense Mutation (SNP) | VAF 109/290 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CAMK4 | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 106/261 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMTA1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 187/439 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCL1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 114/294 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42BPB | c.3309+1G>A p.X1103_splice | Splice Site (SNP) | VAF 147/275 reads (53%) | called by muse, mutect2, varscan2
- CDC42BPB | c.3309G>A p.K1103= | Splice Region (SNP) | VAF 152/282 reads (54%) | called by muse, mutect2, varscan2
- CDH11 | c.2003G>A p.G668D | Missense Mutation (SNP) | VAF 153/219 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR3 | c.3437C>T p.S1146F | Missense Mutation (SNP) | VAF 211/533 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CEMIP | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP99 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CFH | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 134/295 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMYA5 | c.11113C>T p.P3705S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COG7 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 81/169 reads (48%) | called by muse, mutect2, varscan2
- CR2 | c.230_231delinsC p.K77Tfs*19 | Frame Shift Del (DEL) | VAF 97/345 reads (28%) | called by pindel, varscan2*
- CSDE1 | c.596T>A p.F199Y (on ENST00000358528 / NM_001007553.3; = p.F168Y on NM_007158.6) | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CSMD2 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- CSNKA2IP | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 244/468 reads (52%) | SIFT tolerated, low confidence (0.71); PolyPhen probably damaging (0.996); called by muse, varscan2
- CYP3A4 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 128/284 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DCAF12 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 244/319 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DCLK1 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 124/346 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.7417C>T p.L2473F | Missense Mutation (SNP) | VAF 167/409 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- DNAJC8 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 155/386 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DSP | c.2672A>T p.Y891F | Missense Mutation (SNP) | VAF 114/296 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DUOX2 | c.3023C>A p.P1008H | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EP400 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 81/367 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- FAF2 | c.1200del p.K400Nfs*43 | Frame Shift Del (DEL) | VAF 79/228 reads (35%) | called by mutect2, pindel, varscan2
- FAM160A2 | c.1937C>T p.A646V (on ENST00000449352 / NM_001098794.2; = p.A660V on NM_032127.4) | Missense Mutation (SNP) | VAF 87/722 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCC | c.1531C>A p.L511M | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.694); called by mutect2, varscan2
- FLG | c.356A>T p.K119I | Missense Mutation (SNP) | VAF 154/348 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- FMO1 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 119/277 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- FN1 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 148/402 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FXR2 | c.316dup p.Y106Lfs*5 | Frame Shift Ins (INS) | VAF 78/200 reads (39%) | called by mutect2, varscan2
- FXR2 | c.315delinsTT p.E105Dfs*6 | Frame Shift Ins (INS) | VAF 87/311 reads (28%) | called by mutect2*, pindel, varscan2*
- GALNT9 | c.841A>C p.T281P | Missense Mutation (SNP) | VAF 178/410 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by mutect2, varscan2
- GKN3P | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 127/292 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GLE1 | c.669_681del p.E224* | Frame Shift Del (DEL) | VAF 24/218 reads (11%) | called by mutect2, pindel, varscan2
- GPBP1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- HPS4 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 148/338 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HRNR | c.5759C>T p.S1920F | Missense Mutation (SNP) | VAF 162/2231 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2
- HSD17B13 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 137/280 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IGLV4-69 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGA2 | c.2134A>G p.T712A | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KALRN | c.3151C>T p.L1051F | Missense Mutation (SNP) | VAF 169/353 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNT2 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- KDM5C | c.4235C>T p.T1412I | Missense Mutation (SNP) | VAF 160/184 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- KLHL32 | c.743A>T p.H248L | Missense Mutation (SNP) | VAF 134/291 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LAT | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 157/377 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LOXHD1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 128/282 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRCH2 | c.2269A>G p.T757A | Missense Mutation (SNP) | VAF 136/163 reads (83%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC53 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 119/293 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- LUZP4 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 178/213 reads (84%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAGI1 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MBOAT1 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- MFNG | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 168/405 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MGAT4C | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MON2 | c.5099C>T p.P1700L | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- MRC2 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 151/335 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRC2 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 104/293 reads (35%) | called by muse, mutect2, varscan2
- MTAP | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 126/154 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, varscan2
- MTREX | c.1624A>G p.K542E | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- MUC2 | c.1919C>T p.T640I | Missense Mutation (SNP) | VAF 536/749 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUCL3 | c.1448A>G p.N483S (on ENST00000304311; = p.N1359S on NM_080870.4) | Missense Mutation (SNP) | VAF 174/514 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- NCAM2 | c.334T>A p.Y112N | Missense Mutation (SNP) | VAF 147/273 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDNF | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 148/259 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NEB | c.6445G>A p.D2149N | Missense Mutation (SNP) | VAF 106/249 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP2 | c.1478G>A p.R493K | Missense Mutation (SNP) | VAF 222/553 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOXO1 | c.919G>A p.G307R (on ENST00000397280 / NM_172168.3; = p.G301R on NM_144603.4) | Missense Mutation (SNP) | VAF 218/636 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN2 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 467/637 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NUP98 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 312/450 reads (69%) | SIFT tolerated (0.38); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- NUTM2G | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 297/343 reads (87%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NXPE4 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 58/290 reads (20%) | called by muse, mutect2, varscan2
- OR10A3 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 78/706 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OR2T27 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR4D10 | c.202A>T p.I68F | Missense Mutation (SNP) | VAF 285/407 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6S1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- OR6V1 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 195/505 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PALM | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 202/576 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2
- PAPLN | c.2600G>A p.G867E (on ENST00000554301; = p.G840E on NM_173462.4) | Missense Mutation (SNP) | VAF 407/740 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEG3 | c.3044C>A p.P1015H | Missense Mutation (SNP) | VAF 172/372 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PIWIL4 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 123/168 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PKHD1L1 | c.9310A>T p.T3104S | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PLEKHH2 | c.1829C>T p.T610I | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PPRC1 | c.3767C>T p.S1256F | Missense Mutation (SNP) | VAF 137/189 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRDM6 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PSKH2 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RARG | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- REV3L | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- RNLS | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 126/169 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- RPH3A | c.1561C>T p.P521S (on ENST00000389385 / NM_001143854.2; = p.P517S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RTN4R | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 150/409 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR3 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCAMP5 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 138/313 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SGK1 | c.669A>T p.L223F | Missense Mutation (SNP) | VAF 71/100 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SH3PXD2A | c.1301C>T p.S434F (on ENST00000369774 / NM_001365079.1; = p.S406F on NM_014631.2) | Missense Mutation (SNP) | VAF 139/182 reads (76%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SHROOM3 | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 282/527 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- SLC10A6 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPEN | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 124/301 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SPIDR | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPTBN1 | c.4691G>A p.R1564K | Missense Mutation (SNP) | VAF 142/360 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SSR1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SUSD1 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 162/188 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SVEP1 | c.4376C>T p.S1459F | Missense Mutation (SNP) | VAF 205/256 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACC2 | c.4298C>T p.A1433V | Missense Mutation (SNP) | VAF 148/192 reads (77%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, varscan2
- TECTA | c.1154T>G p.V385G | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 119/269 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TGIF2LX | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 120/144 reads (83%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TIMELESS | c.3347C>T p.P1116L | Missense Mutation (SNP) | VAF 104/280 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- TLR4 | c.1111G>A p.D371N (on ENST00000355622 / NM_138554.5; = p.D331N on NM_003266.4) | Missense Mutation (SNP) | VAF 151/191 reads (79%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132B | c.2008C>T p.L670F | Missense Mutation (SNP) | VAF 136/416 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TMEM132E | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 190/507 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM169 | c.86del p.L29Rfs*56 | Frame Shift Del (DEL) | VAF 116/364 reads (32%) | called by mutect2, pindel*, varscan2
- TMEM211 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TMEM247 | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 187/460 reads (41%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMPRSS11B | c.503A>G p.N168S | Missense Mutation (SNP) | VAF 106/233 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TNPO3 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TRBV6-1 | c.197A>C p.Y66S | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, varscan2
- TRBV6-1 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- TTC34 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 189/534 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UBE2E2 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 161/372 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UFL1 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- UNC13C | c.5539G>A p.G1847S | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- VN1R4 | c.214A>G p.R72G | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPS13D | c.2734C>T p.Q912* | Nonsense Mutation (SNP) | VAF 111/275 reads (40%) | called by muse, mutect2, varscan2
- VRK3 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XRCC6 | c.393C>A p.F131L | Missense Mutation (SNP) | VAF 129/342 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- YME1L1 | c.1164del p.A389Pfs*52 (on ENST00000326799 / NM_139312.3; = p.A332Pfs*52 on NM_014263.4) | Frame Shift Del (DEL) | VAF 137/228 reads (60%) | called by mutect2, pindel, varscan2
- ZAR1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 245/624 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED9 | c.3344T>C p.L1115P | Missense Mutation (SNP) | VAF 125/285 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZEB1 | c.3080G>A p.S1027N | Missense Mutation (SNP) | VAF 142/209 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ZFHX4 | c.7483T>G p.C2495G | Missense Mutation (SNP) | VAF 85/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF160 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 114/325 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF280B | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 161/380 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF443 | c.1887T>A p.S629R | Missense Mutation (SNP) | VAF 145/401 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF585A | c.2087G>A p.G696E (on ENST00000292841 / NM_001288800.2; = p.G641E on NM_152655.3) | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF729 | c.534A>T p.K178N | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ABCB5 | c.1731C>T p.I577= (on ENST00000404938 / NM_001163941.2; = p.I132= on NM_178559.6) | Silent (SNP) | VAF 97/265 reads (37%) | catalogued as rs149931729; called by muse, mutect2, varscan2
- ADAM19 | c.2730G>A p.V910= | Silent (SNP) | VAF 95/297 reads (32%) | called by muse, mutect2, varscan2
- ADGRV1 | c.3849G>T p.L1283= | Silent (SNP) | VAF 28/280 reads (10%) | called by muse, mutect2, varscan2
- ADHFE1 | c.1293C>T p.P431= | Silent (SNP) | VAF 113/220 reads (51%) | catalogued as rs754414045; called by muse, mutect2, varscan2
- AK5 | c.1506G>A p.R502= (on ENST00000354567 / NM_174858.3; = p.R476= on NM_012093.4) | Silent (SNP) | VAF 152/362 reads (42%) | called by muse, mutect2, varscan2
- AKAP6 | c.6189C>T p.I2063= | Silent (SNP) | VAF 251/447 reads (56%) | catalogued as COSV55232489; called by muse, mutect2, varscan2
- AKR1B10 | c.225C>T p.I75= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as rs186829500, COSV62055233; called by muse, mutect2, varscan2
- ANAPC7 | c.1197C>T p.A399= | Silent (SNP) | VAF 82/236 reads (35%) | called by muse, mutect2, varscan2
- AP3B2 | c.2211G>A p.Q737= | Silent (SNP) | VAF 91/253 reads (36%) | catalogued as rs544059884, COSV99916859; called by muse, mutect2, varscan2
- ARL9 | c.21G>A p.K7= | Silent (SNP) | VAF 78/198 reads (39%) | called by muse, mutect2, varscan2
- ASIC2 | c.153C>T p.G51= | Silent (SNP) | VAF 180/453 reads (40%) | catalogued as rs1391455208; called by muse, mutect2, varscan2
- ATP1A3 | c.798C>T p.D266= (on ENST00000545399 / NM_001256214.2; = p.D253= on NM_152296.5) | Silent (SNP) | VAF 167/396 reads (42%) | catalogued as rs369131791; called by muse, mutect2, varscan2
- BAZ1B | c.363C>T p.D121= | Silent (SNP) | VAF 71/178 reads (40%) | called by muse, mutect2, varscan2
- CABLES2 | c.732G>A p.K244= | Silent (SNP) | VAF 83/214 reads (39%) | called by muse, mutect2, varscan2
- CAPN11 | c.255C>T p.F85= | Silent (SNP) | VAF 117/297 reads (39%) | catalogued as COSV67236221, COSV67240276; called by muse, mutect2, varscan2
- CARMIL3 | c.838C>T p.L280= | Silent (SNP) | VAF 105/284 reads (37%) | called by muse, mutect2, varscan2
- CCDC151 | c.457C>T p.L153= | Silent (SNP) | VAF 129/330 reads (39%) | catalogued as rs201858348; called by muse, mutect2, varscan2
- CCDC81 | c.603G>A p.R201= (on ENST00000445632 / NM_001156474.2; = p.R111= on NM_021827.4) | Silent (SNP) | VAF 50/312 reads (16%) | catalogued as rs763510233; called by muse, mutect2, varscan2
- CCNB3 | c.1351T>C p.L451= | Silent (SNP) | VAF 249/296 reads (84%) | called by muse, mutect2, varscan2
- CCNY | c.957C>T p.S319= | Silent (SNP) | VAF 154/206 reads (75%) | catalogued as rs766833961; called by muse, varscan2
- CD109 | c.4209C>T p.S1403= | Silent (SNP) | VAF 118/362 reads (33%) | called by muse, mutect2
- CEACAM5 | c.1935C>T p.I645= | Silent (SNP) | VAF 151/399 reads (38%) | called by muse, mutect2, varscan2
- CEP112 | c.1779G>A p.R593= | Silent (SNP) | VAF 104/264 reads (39%) | called by muse, mutect2, varscan2
- CFAP46 | c.1896C>T p.D632= | Silent (SNP) | VAF 231/316 reads (73%) | called by muse, mutect2, varscan2
- CFAP70 | c.2196G>A p.L732= | Silent (SNP) | VAF 93/122 reads (76%) | called by muse, mutect2, varscan2
- CFHR1 | c.960G>A p.G320= | Silent (SNP) | VAF 113/236 reads (48%) | catalogued as COSV57628994; called by muse, mutect2, varscan2
- CHERP | c.1188G>A p.G396= | Silent (SNP) | VAF 195/433 reads (45%) | catalogued as rs780905129; called by muse, mutect2, varscan2
- CMYA5 | c.8170C>T p.L2724= | Silent (SNP) | VAF 52/194 reads (27%) | catalogued as rs1320822319, COSV101484347; called by muse, mutect2, varscan2
- COL11A1 | c.1056G>A p.R352= | Silent (SNP) | VAF 102/246 reads (41%) | catalogued as rs762727530, COSV62171357; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRTAC1 | c.1359G>A p.R453= | Silent (SNP) | VAF 134/195 reads (69%) | called by muse, mutect2, varscan2
- CSMD2 | c.3120G>A p.E1040= | Silent (SNP) | VAF 106/298 reads (36%) | catalogued as COSV53917290, COSV53961596; called by muse, mutect2, varscan2
- CYP2D6 | c.1239C>T p.F413= | Silent (SNP) | VAF 214/600 reads (36%) | called by muse, mutect2, varscan2
- DCAF4L1 | c.273G>A p.Q91= | Silent (SNP) | VAF 118/330 reads (36%) | called by muse, mutect2
- DCAF4L1 | c.1179C>T p.F393= | Silent (SNP) | VAF 46/159 reads (29%) | catalogued as rs1265511978; called by muse, mutect2, varscan2
- DGKI | c.2022C>T p.S674= | Silent (SNP) | VAF 148/344 reads (43%) | called by muse, mutect2, varscan2
- DHX30 | c.558C>T p.G186= (on ENST00000445061 / NM_138615.3; = p.G147= on NM_014966.3) | Silent (SNP) | VAF 154/416 reads (37%) | called by muse, mutect2, varscan2
- DLEC1 | c.606G>A p.R202= | Silent (SNP) | VAF 158/432 reads (37%) | catalogued as rs1228286789, COSV57298331; called by muse, mutect2, varscan2
- DLG2 | c.528C>T p.I176= | Silent (SNP) | VAF 58/433 reads (13%) | catalogued as rs769219035; called by muse, mutect2, varscan2
- DNAH6 | c.1368G>A p.T456= | Silent (SNP) | VAF 93/268 reads (35%) | catalogued as rs372969433; called by muse, mutect2, varscan2
- DNAH6 | c.10479G>A p.K3493= | Silent (SNP) | VAF 63/169 reads (37%) | called by muse, mutect2, varscan2
- DNAH9 | c.13119G>A p.Q4373= | Silent (SNP) | VAF 136/338 reads (40%) | catalogued as rs760755811; called by muse, mutect2
- DOCK6 | c.5463G>A p.Q1821= | Silent (SNP) | VAF 71/182 reads (39%) | called by muse, mutect2, varscan2
- DSC3 | c.2002C>T p.L668= | Silent (SNP) | VAF 134/320 reads (42%) | called by muse, mutect2, varscan2
- ELL | c.990C>T p.F330= | Silent (SNP) | VAF 120/292 reads (41%) | catalogued as COSV99443504; called by muse, mutect2, varscan2
- ERCC6 | c.1183C>T p.L395= | Silent (SNP) | VAF 175/248 reads (71%) | catalogued as rs767647833; called by muse, mutect2, varscan2
- FAM187B | c.777C>T p.S259= | Silent (SNP) | VAF 181/430 reads (42%) | catalogued as rs1330311719; called by muse, mutect2, varscan2
- FAN1 | c.771C>T p.F257= | Silent (SNP) | VAF 151/353 reads (43%) | catalogued as rs372989498; called by muse, mutect2, varscan2
- FAT3 | c.4785A>G p.K1595= | Silent (SNP) | VAF 53/356 reads (15%) | called by muse, mutect2, varscan2
- FREM2 | c.5601C>T p.F1867= | Silent (SNP) | VAF 94/233 reads (40%) | catalogued as COSV54846828; called by muse, mutect2, varscan2
- FRMPD3 | c.1587G>A p.G529= | Silent (SNP) | VAF 193/217 reads (89%) | catalogued as COSV99346155; called by muse, mutect2, varscan2
- GDPD4 | c.57C>T p.V19= | Silent (SNP) | VAF 42/211 reads (20%) | called by muse, mutect2, varscan2
- GGT2 | c.1278C>T p.L426= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as rs1291901474; called by mutect2, varscan2
- GIPR | c.342C>T p.D114= | Silent (SNP) | VAF 83/212 reads (39%) | called by muse, mutect2, varscan2
- GNPTAB | c.3711G>A p.R1237= | Silent (SNP) | VAF 66/196 reads (34%) | catalogued as rs1251057066; called by muse, mutect2, varscan2
- GPI | c.225G>A p.R75= | Silent (SNP) | VAF 126/333 reads (38%) | catalogued as rs1364734053; called by muse, mutect2, varscan2
- GRID2IP | c.774G>A p.P258= | Silent (SNP) | VAF 199/470 reads (42%) | catalogued as rs902347614; called by muse, mutect2, varscan2
- GRIN2A | c.2409G>A p.E803= | Silent (SNP) | VAF 82/249 reads (33%) | called by muse, mutect2, varscan2
- GRM3 | c.678G>A p.G226= | Silent (SNP) | VAF 144/347 reads (41%) | catalogued as rs745376739, COSV64479515; called by muse, mutect2, varscan2
- HEPHL1 | c.1857C>T p.N619= | Silent (SNP) | VAF 148/213 reads (69%) | called by muse, mutect2, varscan2
- HEYL | c.921G>A p.G307= | Silent (SNP) | VAF 188/459 reads (41%) | catalogued as rs554192451; called by muse, mutect2, varscan2
- HLA-G | c.774G>A p.R258= | Silent (SNP) | VAF 122/364 reads (34%) | called by muse, mutect2, varscan2
- HMGB4 | c.501G>A p.R167= | Silent (SNP) | VAF 142/346 reads (41%) | called by muse, mutect2, varscan2
- HMSD | c.261G>A p.T87= | Silent (SNP) | VAF 76/208 reads (37%) | catalogued as rs1384875525, COSV101282944, COSV68816978; called by muse, mutect2, varscan2
- HOXD8 | c.234C>T p.P78= | Silent (SNP) | VAF 295/711 reads (41%) | catalogued as rs962288410; called by muse, mutect2, varscan2
- HTT | c.6850C>T p.L2284= | Silent (SNP) | VAF 190/497 reads (38%) | called by muse, mutect2, varscan2
- ICE1 | c.6696C>T p.S2232= | Silent (SNP) | VAF 229/404 reads (57%) | called by muse, mutect2, varscan2
- IDO1 | c.24C>T p.S8= | Silent (SNP) | VAF 67/149 reads (45%) | called by muse, mutect2, varscan2
- IFNW1 | c.64C>T p.L22= | Silent (SNP) | VAF 217/258 reads (84%) | called by muse, mutect2, varscan2
- IGFN1 | c.555G>A p.K185= | Silent (SNP) | VAF 118/295 reads (40%) | catalogued as rs780511622; called by muse, mutect2, varscan2
- IGSF10 | c.3402C>T p.S1134= | Silent (SNP) | VAF 119/370 reads (32%) | catalogued as COSV56791089; called by muse, mutect2, varscan2
- IGSF10 | c.1938G>A p.V646= | Silent (SNP) | VAF 183/389 reads (47%) | called by muse, mutect2, varscan2
- IGSF9 | c.1908C>G p.P636= (on ENST00000368094 / NM_001135050.2; = p.P620= on NM_020789.4) | Silent (SNP) | VAF 179/484 reads (37%) | called by muse, mutect2, varscan2
- IL1RL1 | c.1048C>T p.L350= | Silent (SNP) | VAF 73/218 reads (33%) | called by muse, mutect2, varscan2
- INF2 | c.999C>T p.T333= | Silent (SNP) | VAF 244/408 reads (60%) | called by muse, mutect2, varscan2
- INPPL1 | c.2157C>T p.S719= | Silent (SNP) | VAF 213/317 reads (67%) | called by muse, mutect2, varscan2
- INTS7 | c.366C>T p.T122= | Silent (SNP) | VAF 68/137 reads (50%) | catalogued as rs1356188614; called by muse, mutect2, varscan2
- IQCN | c.1638C>T p.S546= | Silent (SNP) | VAF 146/364 reads (40%) | called by muse, mutect2, varscan2
- KCNB2 | c.1371C>T p.A457= | Silent (SNP) | VAF 68/283 reads (24%) | called by muse, mutect2, varscan2
- KCNJ10 | c.471G>A p.L157= | Silent (SNP) | VAF 142/353 reads (40%) | called by muse, mutect2, varscan2
- KCNT1 | c.2052G>A p.S684= (on ENST00000488444; = p.S703= on NM_020822.3) | Silent (SNP) | VAF 450/550 reads (82%) | catalogued as rs767200583, COSV53706020; called by muse, mutect2, varscan2
- KDM5C | c.4236C>T p.T1412= | Silent (SNP) | VAF 158/183 reads (86%) | called by muse, mutect2, varscan2
- KERA | c.576G>A p.K192= | Silent (SNP) | VAF 111/284 reads (39%) | catalogued as COSV99899350; called by muse, mutect2, varscan2
- KIR3DL1 | c.306C>T p.S102= | Silent (SNP) | VAF 128/328 reads (39%) | catalogued as rs1229083521, COSV100428889; called by muse, mutect2, varscan2
- KIR3DL1 | c.840C>T p.F280= | Silent (SNP) | VAF 81/209 reads (39%) | catalogued as rs765913238, COSV58487495; called by muse, mutect2
- KRT78 | c.423G>A p.T141= | Silent (SNP) | VAF 143/335 reads (43%) | catalogued as rs116002883; called by muse, mutect2, varscan2
- L3MBTL4 | c.399C>T p.S133= | Silent (SNP) | VAF 100/271 reads (37%) | catalogued as COSV99531972; called by muse, mutect2, varscan2
- LMO7 | c.2916C>T p.P972= (on ENST00000357063; = p.P653= on NM_005358.5) | Silent (SNP) | VAF 132/378 reads (35%) | catalogued as rs371242913; called by muse, mutect2, varscan2
- LRAT | c.429G>A p.R143= | Silent (SNP) | VAF 32/382 reads (8%) | called by muse, mutect2
- LRFN2 | c.78C>T p.V26= | Silent (SNP) | VAF 153/370 reads (41%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.1062C>T p.F354= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as rs868643467; called by muse, mutect2, varscan2
- LRRN2 | c.1554C>T p.L518= | Silent (SNP) | VAF 158/420 reads (38%) | called by muse, mutect2, varscan2
- MAGEC2 | c.27C>T p.F9= | Silent (SNP) | VAF 151/189 reads (80%) | catalogued as COSV99909748; called by muse, mutect2, varscan2
- MGAM2 | c.3070C>T p.L1024= | Silent (SNP) | VAF 128/321 reads (40%) | called by muse, mutect2, varscan2
- MSX1 | c.831C>T p.P277= | Silent (SNP) | VAF 255/619 reads (41%) | called by muse, mutect2, varscan2
- MTHFR | c.594C>T p.P198= | Silent (SNP) | VAF 101/223 reads (45%) | called by muse, mutect2, varscan2
- MUC16 | c.12276C>T p.I4092= | Silent (SNP) | VAF 149/340 reads (44%) | catalogued as rs756263109, COSV67465143; called by muse, mutect2, varscan2
- MYH14 | c.135C>T p.S45= | Silent (SNP) | VAF 78/552 reads (14%) | called by muse, mutect2, varscan2
- MYO1F | c.2964C>T p.S988= | Silent (SNP) | VAF 166/413 reads (40%) | catalogued as rs1157388117, COSV57795253; called by muse, mutect2, varscan2
- MYO7A | c.5394G>A p.Q1798= | Silent (SNP) | VAF 83/477 reads (17%) | called by muse, mutect2, varscan2
- NCF1 | c.537G>A p.T179= | Silent (SNP) | VAF 70/199 reads (35%) | catalogued as rs781784127; called by muse, mutect2, varscan2
- NHSL2 | c.2122C>T p.L708= (on ENST00000510661; = p.L1074= on NM_001013627.2) | Silent (SNP) | VAF 69/88 reads (78%) | called by muse, mutect2, varscan2
- NKX2-3 | c.259C>T p.L87= | Silent (SNP) | VAF 112/176 reads (64%) | catalogued as COSV104419505; called by muse, mutect2, varscan2
- NLRP9 | c.1476G>A p.G492= | Silent (SNP) | VAF 132/355 reads (37%) | catalogued as COSV60464408; called by muse, mutect2, varscan2
- NRIP1 | c.2148C>T p.L716= | Silent (SNP) | VAF 129/469 reads (28%) | catalogued as rs185987444; called by muse, mutect2, varscan2
- NRXN2 | c.4050G>A p.A1350= | Silent (SNP) | VAF 459/631 reads (73%) | catalogued as rs761962421, COSV55457036; called by muse, mutect2, varscan2
- NXPE2 | c.1299G>A p.R433= | Silent (SNP) | VAF 284/400 reads (71%) | called by muse, mutect2, varscan2
- OPHN1 | c.1821G>A p.L607= | Silent (SNP) | VAF 151/174 reads (87%) | called by muse, mutect2, varscan2
- OR2AP1 | c.663G>A p.K221= | Silent (SNP) | VAF 128/320 reads (40%) | catalogued as rs747269576; called by muse, mutect2, varscan2
- OR2F1 | c.675C>T p.I225= | Silent (SNP) | VAF 130/386 reads (34%) | catalogued as rs1160336390; called by muse, mutect2, varscan2
- OR4C5 | c.195C>T p.I65= | Silent (SNP) | VAF 67/386 reads (17%) | called by muse, mutect2, varscan2
- OR4E1 | c.108C>T p.L36= | Silent (SNP) | VAF 106/277 reads (38%) | called by muse, mutect2, varscan2
- OR51S1 | c.780C>T p.I260= | Silent (SNP) | VAF 58/604 reads (10%) | catalogued as rs866618850, COSV59059712; called by muse, mutect2
- OR5B3 | c.663C>T p.I221= | Silent (SNP) | VAF 176/262 reads (67%) | catalogued as rs146606547; called by muse, mutect2
- OR8J1 | c.882G>A p.R294= | Silent (SNP) | VAF 245/367 reads (67%) | catalogued as rs759451788, COSV57316805; called by muse, mutect2, varscan2
- PAPLN | c.1791C>T p.G597= (on ENST00000554301; = p.G570= on NM_173462.4) | Silent (SNP) | VAF 432/801 reads (54%) | catalogued as rs766691028; called by mutect2, varscan2
- PBXIP1 | c.1141C>T p.L381= | Silent (SNP) | VAF 166/391 reads (42%) | called by muse, mutect2, varscan2
- PBXIP1 | c.1140C>T p.F380= | Silent (SNP) | VAF 165/392 reads (42%) | catalogued as COSV63777595; called by muse, mutect2, varscan2
- PCDHGA8 | c.1383C>T p.I461= | Silent (SNP) | VAF 119/147 reads (81%) | catalogued as COSV53988605; called by muse, mutect2, varscan2
- PDE11A | c.2787G>A p.K929= | Silent (SNP) | VAF 88/211 reads (42%) | catalogued as rs1281037960; called by muse, mutect2, varscan2
- PERM1 | c.1776C>T p.I592= | Silent (SNP) | VAF 160/382 reads (42%) | catalogued as rs1261580971, COSV58023883; called by muse, mutect2
- PERM1 | c.1737C>T p.T579= | Silent (SNP) | VAF 148/380 reads (39%) | catalogued as rs1212283847; called by muse, mutect2
- PLIN3 | c.1191C>A p.A397= | Silent (SNP) | VAF 144/382 reads (38%) | catalogued as rs752138898; called by muse, mutect2, varscan2
- POTEA | c.291G>A p.K97= | Silent (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
- POTEF | c.390G>A p.E130= | Silent (SNP) | VAF 111/273 reads (41%) | called by muse, mutect2, varscan2
- PPEF2 | c.2253T>C p.G751= | Silent (SNP) | VAF 80/155 reads (52%) | called by muse, mutect2, varscan2
- PPP3CC | c.54C>T p.V18= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs201721168; called by muse, mutect2, varscan2
- PSG4 | c.759G>A p.E253= | Silent (SNP) | VAF 74/210 reads (35%) | called by muse, mutect2, varscan2
- PSMC1 | c.1080G>A p.T360= | Silent (SNP) | VAF 211/402 reads (52%) | catalogued as rs781271442, COSV99728436; called by muse, mutect2, varscan2
- PSMD6 | c.132C>T p.A44= | Silent (SNP) | VAF 181/506 reads (36%) | called by muse, mutect2, varscan2
- PTPRD | c.4311G>A p.G1437= | Silent (SNP) | VAF 243/295 reads (82%) | catalogued as rs1251038630, COSV100642788; called by muse, mutect2, varscan2
- RGS9BP | c.522C>T p.T174= | Silent (SNP) | VAF 218/562 reads (39%) | catalogued as rs769710405; called by muse, mutect2, varscan2
- RHBDD2 | c.642C>T p.L214= | Silent (SNP) | VAF 134/270 reads (50%) | catalogued as rs782573934, COSV50087584; called by muse, mutect2, varscan2
- RNF165 | c.348C>T p.A116= | Silent (SNP) | VAF 122/327 reads (37%) | called by muse, mutect2, varscan2
- RNF39 | c.268C>T p.L90= | Silent (SNP) | VAF 326/822 reads (40%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.783G>A p.G261= | Silent (SNP) | VAF 120/193 reads (62%) | catalogued as rs766456537; called by muse, mutect2, varscan2
- SBK3 | c.1056G>A p.T352= | Silent (SNP) | VAF 178/387 reads (46%) | catalogued as rs1005087489; called by muse, mutect2, varscan2
- SCN1A | c.3414G>A p.L1138= (on ENST00000303395 / NM_001202435.3; = p.L1127= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- SCUBE3 | c.2628G>A p.E876= | Silent (SNP) | VAF 137/339 reads (40%) | called by muse, mutect2, varscan2
- SEMA4B | c.1419C>T p.L473= | Silent (SNP) | VAF 126/318 reads (40%) | called by muse, mutect2, varscan2
- SIAE | c.285C>T p.F95= | Silent (SNP) | VAF 52/302 reads (17%) | catalogued as rs147638217; called by muse, mutect2, varscan2
- SLA2 | c.348G>A p.G116= | Silent (SNP) | VAF 135/326 reads (41%) | called by muse, mutect2, varscan2
- SLC22A9 | c.1140C>T p.F380= | Silent (SNP) | VAF 239/352 reads (68%) | catalogued as COSV54165816; called by muse, mutect2, varscan2
- SLC5A5 | c.1701C>T p.L567= | Silent (SNP) | VAF 117/309 reads (38%) | catalogued as rs375404000, COSV55835703; ClinVar: likely benign; called by muse, mutect2, varscan2
- SORL1 | c.1470G>A p.R490= | Silent (SNP) | VAF 58/385 reads (15%) | called by muse, mutect2, varscan2
- SP100 | c.2385C>T p.F795= | Silent (SNP) | VAF 100/279 reads (36%) | catalogued as rs543288909, COSV60844606; called by muse, mutect2, varscan2
- SPG11 | c.2058C>T p.L686= | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as COSV55991943; called by muse, mutect2, varscan2
- SPIDR | c.42G>A p.R14= | Silent (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- SPTA1 | c.3471C>T p.I1157= | Silent (SNP) | VAF 83/190 reads (44%) | catalogued as COSV100934121; called by muse, mutect2, varscan2
- STXBP2 | c.888C>T p.I296= | Silent (SNP) | VAF 119/264 reads (45%) | catalogued as rs1350527680, COSV99657421; called by muse, mutect2, varscan2
- TAF3 | c.2421C>T p.L807= | Silent (SNP) | VAF 220/319 reads (69%) | catalogued as rs761732712, COSV60206814; called by muse, mutect2, varscan2
- TCF4 | c.1578G>A p.T526= | Silent (SNP) | VAF 153/344 reads (44%) | catalogued as rs774527851, COSV61895509; called by muse, mutect2, varscan2
- TIMELESS | c.828T>G p.S276= | Silent (SNP) | VAF 62/181 reads (34%) | called by muse, mutect2, varscan2
- TMEM132E | c.1884G>A p.L628= (on ENST00000321639; = p.L718= on NM_001304438.2) | Silent (SNP) | VAF 158/365 reads (43%) | catalogued as COSV58695152; called by muse, mutect2, varscan2
- TNFRSF17 | c.450G>A p.E150= | Silent (SNP) | VAF 114/311 reads (37%) | catalogued as rs1259565059; called by muse, mutect2, varscan2
- TNFSF8 | c.633C>T p.F211= | Silent (SNP) | VAF 247/282 reads (88%) | catalogued as rs778760383; called by muse, mutect2, varscan2
- TNK2 | c.1221C>T p.I407= | Silent (SNP) | VAF 168/383 reads (44%) | called by muse, mutect2, varscan2
- TRABD2B | c.744G>A p.T248= | Silent (SNP) | VAF 174/379 reads (46%) | catalogued as rs918051247; called by muse, mutect2, varscan2
- TSHZ1 | c.738C>T p.F246= (on ENST00000580243 / NM_001308210.2; = p.F201= on NM_005786.6) | Silent (SNP) | VAF 171/418 reads (41%) | called by muse, varscan2
- TTC19 | c.384G>A p.Q128= | Silent (SNP) | VAF 109/264 reads (41%) | catalogued as COSV55422824; called by muse, mutect2, varscan2
- TTC34 | c.2844C>T p.A948= | Silent (SNP) | VAF 176/490 reads (36%) | catalogued as rs780050508; called by mutect2, varscan2
- TTN | c.101808G>A p.K33936= (on ENST00000591111; = p.K26512= on NM_003319.4) | Silent (SNP) | VAF 121/297 reads (41%) | catalogued as COSV59990384; called by muse, mutect2, varscan2
- UBE4B | c.3297C>T p.I1099= (on ENST00000343090 / NM_001105562.3; = p.I970= on NM_006048.5) | Silent (SNP) | VAF 107/307 reads (35%) | called by muse, mutect2, varscan2
- UGT2A3 | c.1386C>T p.I462= | Silent (SNP) | VAF 173/416 reads (42%) | catalogued as rs755442651; called by muse, mutect2, varscan2
- VGLL3 | c.645G>A p.V215= | Silent (SNP) | VAF 188/436 reads (43%) | catalogued as rs1262306356, COSV101052088; called by muse, mutect2, varscan2
- WNT2 | c.402C>T p.S134= | Silent (SNP) | VAF 141/371 reads (38%) | catalogued as COSV99625849; called by muse, mutect2, varscan2
- YME1L1 | c.1167C>A p.A389= (on ENST00000326799 / NM_139312.3; = p.A332= on NM_014263.4) | Silent (SNP) | VAF 134/178 reads (75%) | called by mutect2, varscan2
- ZAR1 | c.240G>A p.R80= | Silent (SNP) | VAF 247/627 reads (39%) | catalogued as rs1406762909; called by muse, mutect2, varscan2
- ZFPM2 | c.3264G>A p.E1088= | Silent (SNP) | VAF 48/223 reads (22%) | called by muse, mutect2, varscan2
- ZFYVE1 | c.648C>T p.S216= | Silent (SNP) | VAF 117/355 reads (33%) | catalogued as rs1479647184; called by muse, mutect2, varscan2
- C4orf50 | chr4:5990691 G>A | 5'Flank (SNP) | VAF 165/410 reads (40%) | called by muse, mutect2, varscan2
- CD163 | c.47-162A>G | Intron (SNP) | VAF 108/270 reads (40%) | catalogued as rs969953393; called by muse, mutect2, varscan2
- DAZL | c.3+707G>A | Intron (SNP) | VAF 153/388 reads (39%) | called by muse, mutect2, varscan2
- DIRC1 | n.352C>T | RNA (SNP) | VAF 141/367 reads (38%) | catalogued as rs745669182; called by muse, mutect2, varscan2
- EEF1D | c.-7-2464C>T | Intron (SNP) | VAF 175/371 reads (47%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-2465C>A | Intron (SNP) | VAF 176/370 reads (48%) | called by muse, mutect2, varscan2
- FBXW7 | c.501+29031A>C | Intron (SNP) | VAF 88/281 reads (31%) | called by muse, mutect2, varscan2
- GLYATL1 | c.-102G>A | 5'UTR (SNP) | VAF 213/303 reads (70%) | catalogued as COSV55609865; called by muse, mutect2, varscan2
- GSDME | c.990+47G>A | Intron (SNP) | VAF 144/336 reads (43%) | called by muse, mutect2, varscan2
- HSPH1 | chr13:31162076 G>A | 5'Flank (SNP) | VAF 180/479 reads (38%) | called by muse, mutect2, varscan2
- KCNK12 | c.*8536C>T | 3'UTR (SNP) | VAF 122/283 reads (43%) | catalogued as rs776464665; called by muse, mutect2, varscan2
- MRPL4 | c.740-407C>T | Intron (SNP) | VAF 106/294 reads (36%) | called by muse, mutect2, varscan2
- NACA | c.70+3994C>T | Intron (SNP) | VAF 132/308 reads (43%) | called by muse, mutect2, varscan2
- NADK | c.263+2123A>T | Intron (SNP) | VAF 178/429 reads (41%) | called by muse, mutect2, varscan2
- NEB | c.11602-3158C>G | Intron (SNP) | VAF 114/536 reads (21%) | called by muse, mutect2
- OAS3 | c.460+43C>T | Intron (SNP) | VAF 120/355 reads (34%) | catalogued as rs779823267; called by muse, mutect2, varscan2
- OR2T2 | chr1:248441859 G>A | 5'Flank (SNP) | VAF 56/726 reads (8%) | called by muse, mutect2
- PRDX6 | chr1:173476832 G>A | 5'Flank (SNP) | VAF 189/462 reads (41%) | called by muse, mutect2, varscan2
- PRF1 | c.*224C>T | 3'UTR (SNP) | VAF 62/101 reads (61%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2362-1726G>A | Intron (SNP) | VAF 227/470 reads (48%) | called by muse, mutect2, varscan2
- VPS11 | chr11:119069179 C>T | 5'Flank (SNP) | VAF 24/212 reads (11%) | catalogued as rs782544005; called by muse, mutect2, varscan2
- XKR6 | c.*1G>A | 3'UTR (SNP) | VAF 110/189 reads (58%) | called by muse, mutect2, varscan2
- ZNF415 | c.136+590G>A | Intron (SNP) | VAF 88/230 reads (38%) | called by muse, mutect2, varscan2
